Somatic mutation profile of tumor specimen 0DCM1K from CCDI case PBBMSY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.5 years (906 days).
Specimen 0DCM1K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26693e96-325f-4bd8-b2a5-c9e5adde0560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f05cf89e-3db4-4a99-a6f0-22afdb639e73

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 322/814 reads (40%) | catalogued as rs752866106; called by mutect2, varscan2
- NPAT | c.4052C>A p.P1351H | Missense Mutation (SNP) | VAF 29/906 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCD3 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 364/856 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.025); called by mutect2, varscan2
- CXorf56 | c.-50C>T | 5'UTR (SNP) | VAF 135/295 reads (46%) | catalogued as rs766202946; called by muse, mutect2, varscan2
